CPTAC case C3L-02116 — Pancreas — Ductal and Lobular Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d2f97b9f-30fc-48cf-8120-e7d1d3c4f71f

Demographics
Sex at birth: male; Race: asian; Year of birth: 1949; Vital status: Dead; Days to death: 1,063 days (2.9 years); Year of death: 2020; Cause of death: Cancer Related; Country of birth: China.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Body of pancreas; Age at diagnosis: 67.6 years (24,692 days); Year of diagnosis: 2017; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 1,063 days (2.9 years); Progression or recurrence: yes; Days to recurrence: 673 days (1.8 years); Days to last follow up: 1,024 days (2.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 2.5 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 14; Lymphatic invasion present: No; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (4 entries)
- Days to follow up: 317 days; Disease response: Complete Response.
- Days to follow up: 716 days (2.0 years); Disease response: Progressive Disease; Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,003 days (2.7 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 673 days (1.8 years); Karnofsky performance status: 60; ECOG performance status: 2.
- Days to follow up: 1,024 days (2.8 years); Disease response: With Tumor; Karnofsky performance status: 50; ECOG performance status: 2.

Other clinical attributes
- Weight: 76 kg; Height: 170 cm; BMI: 26.3; Comorbidities: Pancreatitis; Diabetes treatment type: Insulin.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking onset year: 1975; Tobacco smoking quit year: 1977; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker; Exposure duration years: 2.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02116-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -42 days; Initial weight: 144 mg; Time between excision and freezing: 33 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02116-21: Section location: Body; Percent tumor nuclei: 25; Percent necrosis: 0.
- Sample C3L-02116-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 71 mg.
- Sample C3L-02116-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -42 days; Initial weight: 67 mg; Time between excision and freezing: 35 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02116-23: Section location: Body; Percent tumor nuclei: 50; Percent necrosis: 0.
- Sample C3L-02116-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -42 days; Initial weight: 101 mg; Time between excision and freezing: 39 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-02116-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -42 days; Method of sample procurement: Blood Draw.
- Sample C3L-02116-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
